Somatic mutation profile of tumor specimen TCGA-BS-A0TG-01A (aliquot TCGA-BS-A0TG-01A-32D-A10B-09) from TCGA case TCGA-BS-A0TG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 60.4 years (22,043 days).
Specimen TCGA-BS-A0TG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) def2b5bb-b645-4b81-b9cd-71b5bbc1bca7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0TG-10A (Blood Derived Normal), aliquot TCGA-BS-A0TG-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb9f0bb5-2a49-492d-99ba-21511b7681b2

The open-access MAF lists 45 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 35/72 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC1 | c.1827G>A p.A609= | Splice Region (SNP) | VAF 16/38 reads (42%) | catalogued as rs758909835, COSV60693612; called by muse, mutect2, varscan2
- ABTB1 | c.761G>A p.R254Q (on ENST00000232744 / NM_172027.3; = p.R112Q on NM_032548.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.514); catalogued as rs375860467; called by muse, mutect2, varscan2
- BAZ2A | c.3694C>A p.Q1232K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.262); catalogued as rs1237068505, COSV51643420; called by muse, mutect2
- COL5A1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.935); catalogued as rs776904091, COSV65665757; called by muse, mutect2, varscan2
- DCAF12L2 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63584037, COSV63584108; called by muse, mutect2
- DCLK1 | c.2095C>T p.R699* (on ENST00000360631 / NM_001330072.2; = p.D723= on NM_004734.5) | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV55192917; called by muse, mutect2, varscan2
- DNAI1 | c.1487T>C p.V496A | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs748133557, COSV54284558; called by muse, mutect2, varscan2
- DUSP22 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs368265261; called by muse, mutect2, varscan2
- EIF4G3 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs368799178; called by muse, mutect2, varscan2
- GLUD2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60153043; called by muse, mutect2, varscan2
- GPT | c.1433G>C p.R478P | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV52954797; called by muse, mutect2, varscan2
- H1-4 | c.280G>C p.V94L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.32); catalogued as COSV56803009, COSV56803466; called by muse, mutect2, varscan2
- HMGCS1 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349756701, COSV57291525; called by muse, mutect2, varscan2
- LGMN | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58405118; called by muse, mutect2, varscan2
- MAB21L2 | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58263527; called by muse, mutect2, varscan2
- MYH2 | c.4735G>C p.D1579H | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55447835; called by muse, mutect2, varscan2
- NRXN1 | c.3499C>T p.R1167* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as rs199546979, COSV58438923, COSV58455553; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PKD2L1 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58398726; called by muse, mutect2, varscan2
- SCML4 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV64637995; called by muse, mutect2, varscan2
- SIK3 | c.1997G>A p.R666Q (on ENST00000445177 / NM_001366686.2; = p.R624Q on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767024932, COSV52622977; called by muse, mutect2, varscan2
- SLC35A2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as rs151120284, COSV55946286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD2 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as COSV51015228, COSV51052323, COSV51062639; called by muse, mutect2, varscan2
- TMEM200A | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51659265; called by muse, mutect2, varscan2
- TRIM3 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs763745606, COSV61985534; called by muse, mutect2, varscan2
- XRN1 | c.2182G>A p.V728M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs957639843, COSV53817920; called by muse, mutect2, varscan2
- ZMYND8 | c.1658G>C p.R553P (on ENST00000311275 / NM_001363741.2; = p.R573P on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV53683204, COSV53696011; called by muse, mutect2, varscan2
- ZNF211 | c.1331G>T p.R444L (on ENST00000347302 / NM_198855.4; = p.R457L on NM_006385.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV53745419; called by muse, mutect2, varscan2
- ARID1A | c.1244_1251del p.H415Pfs*205 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- ARID1A | c.6706del p.R2236Afs*31 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- ANKFN1 | c.363A>C p.T121= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV59459356; called by muse, mutect2, varscan2
- ANKK1 | c.1746C>T p.Y582= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs373856752; called by muse, mutect2, varscan2
- CPLX2 | c.87C>T p.D29= | Silent (SNP) | VAF 2/14 reads (14%) | catalogued as rs1393699238, COSV64002143; called by muse, mutect2
- FAM177B | c.141G>A p.K47= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV62601813; called by muse, mutect2, varscan2
- HRNR | c.888C>T p.H296= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs142350682; called by muse, mutect2, varscan2
- LARGE2 | c.405C>T p.A135= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs149049026, COSV57686460; called by muse, mutect2
- PCDHB9 | c.2214C>T p.D738= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1209435443, COSV53383536; called by muse, mutect2, varscan2
- PCDHGA9 | c.387C>T p.S129= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV54027364; called by muse, mutect2
- SLC1A4 | c.1197A>G p.V399= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1309959702, COSV52235946; called by muse, mutect2, varscan2
- SPA17 | c.6G>A p.S2= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs374373269; called by muse, varscan2
- STAT1 | c.1890G>A p.A630= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs757407974, COSV63117425; called by muse, mutect2
- VWA8 | c.2433C>A p.T811= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV55705114; called by muse, mutect2, varscan2
- MYH7 | c.4169+188G>A | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as rs769758929, COSV62516476, COSV62524143; called by muse, mutect2, varscan2
